Somatic mutation profile of tumor specimen TARGET-10-PANWJR-09A (aliquot TARGET-10-PANWJR-09A-01D) from TARGET case TARGET-10-PANWJR, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.3 years (1,940 days).
Specimen TARGET-10-PANWJR-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 66942f40-cc98-4d38-9207-0db368f26b73.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PANWJR-10A (Blood Derived Normal), aliquot TARGET-10-PANWJR-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e5420353-9d50-4971-9609-1060605ca68f

The open-access MAF lists 56 somatic variants for this specimen: 33 protein-altering or splice-affecting, 11 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 11, Intron 7, Nonsense Mutation 4, 3'UTR 3, Splice Region 1, Splice Site 1, 5'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 13/54 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADGRG2 | c.391G>A p.D131N (on ENST00000379869 / NM_001079858.3; = p.D128N on NM_005756.4) | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.007); catalogued as rs1189130669; called by muse, mutect2, varscan2
- CMIP | c.1267G>A p.D423N (on ENST00000537098 / NM_198390.2; = p.D329N on NM_030629.3) | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as rs781118185; called by muse, mutect2, varscan2
- FAM83A | c.194C>T p.S65L | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.671); catalogued as rs776658008, COSV99414437; called by muse, mutect2, varscan2
- GABRB2 | c.355G>C p.D119H | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50917841; called by muse, mutect2, varscan2
- KLF6 | c.755G>A p.R252Q | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1170260252, COSV51494080, COSV99434913; called by muse, mutect2, varscan2
- LAMA2 | c.2767G>A p.G923S | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs144492513; ClinVar: uncertain significance; called by muse, mutect2
- MYO15A | c.5171G>A p.R1724H | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs774345883, COSV52769397; called by muse, mutect2, varscan2
- NSD2 | c.3295G>A p.E1099K | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs772470710, COSV56386422; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PHC2 | c.1769C>T p.S590L (on ENST00000257118 / NM_198040.2; = p.S55L on NM_004427.4) | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.044); catalogued as rs535258974; called by muse, mutect2
- PIPOX | c.488G>A p.R163Q | Missense Mutation (SNP) | VAF 34/60 reads (57%) | SIFT tolerated (0.58); PolyPhen benign (0.013); catalogued as rs142705261; called by muse, mutect2, varscan2
- PSPC1 | c.1465C>G p.Q489E | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.585); catalogued as COSV100142125; called by muse, mutect2, varscan2
- RIPK3 | c.334C>T p.R112W | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.525); catalogued as rs777875133, COSV53475493; called by muse, mutect2, varscan2
- RUFY1 | c.1642G>A p.E548K | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.562); catalogued as COSV60160655; called by muse, mutect2, varscan2
- SGTA | c.210G>A p.E70= | Splice Region (SNP) | VAF 8/18 reads (44%) | catalogued as rs1233780514; called by muse, mutect2
- SIGLECL1 | c.411-1G>A p.X137_splice | Splice Site (SNP) | VAF 3/45 reads (7%) | catalogued as COSV57062791; called by muse, mutect2
- UBA2 | c.319C>T p.R107* | Nonsense Mutation (SNP) | VAF 32/58 reads (55%) | catalogued as COSV55831179; called by muse, mutect2, varscan2
- ABCA5 | c.2171C>A p.S724Y | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- ARHGEF18 | c.979C>T p.Q327* (on ENST00000359920 / NM_001130955.2; = p.Q223* on NM_015318.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 21/64 reads (33%) | called by muse, mutect2, varscan2
- BAZ2A | c.215C>G p.S72C | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- CLSTN2 | c.2218G>A p.G740S | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.194); called by muse, mutect2
- COL4A6 | c.646G>A p.D216N | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.409); called by muse, mutect2, varscan2
- FAM149A | c.2098_2099insGATAGGA p.S700* (on ENST00000356371 / NM_001367768.2; = p.S409* on NM_015398.3 and 3 other RefSeq transcripts) | Nonsense Mutation (INS) | VAF 31/103 reads (30%) | called by mutect2, pindel*, varscan2
- IFIT5 | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- INPP5J | c.2239G>C p.D747H (on ENST00000331075 / NM_001284285.2; = p.D379H on NM_001002837.2) | Missense Mutation (SNP) | VAF 15/21 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- INPP5J | c.2599G>C p.E867Q (on ENST00000331075 / NM_001284285.2; = p.E499Q on NM_001002837.2) | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- LUZP4 | c.544A>T p.R182* | Nonsense Mutation (SNP) | VAF 28/60 reads (47%) | called by muse, mutect2, varscan2
- MBTPS2 | c.1447G>A p.V483M | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.64); called by muse, mutect2, varscan2
- OTULIN | c.419G>A p.S140N | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- PMCH | c.70C>G p.L24V | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- PTPN13 | c.6367G>C p.E2123Q (on ENST00000411767 / NM_080683.3; = p.E2104Q on NM_006264.3) | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.33); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- TRPS1 | c.1222G>A p.D408N (on ENST00000220888 / NM_001330599.2; = p.D421N on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/52 reads (58%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF423 | c.945G>C p.E315D (on ENST00000563137 / NM_001379286.1; = p.E307D on NM_015069.4) | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.479); called by muse, mutect2, varscan2
- AASDH | c.3201C>T p.V1067= | Silent (SNP) | VAF 10/186 reads (5%) | catalogued as COSV52709905; called by muse, mutect2
- CEBPA | c.885G>A p.A295= | Silent (SNP) | VAF 11/72 reads (15%) | called by muse, mutect2, varscan2
- ERCC2 | c.1983C>G p.A661= | Silent (SNP) | VAF 31/71 reads (44%) | called by muse, mutect2, varscan2
- FHL2 | c.372G>A p.E124= | Silent (SNP) | VAF 7/53 reads (13%) | called by muse, mutect2, varscan2
- MN1 | c.2958C>T p.V986= | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as rs1321900688, COSV56558693; called by muse, mutect2, varscan2
- PCDHGA8 | c.237G>A p.P79= | Silent (SNP) | VAF 18/38 reads (47%) | catalogued as rs1270447503; called by muse, mutect2, varscan2
- PGR | c.207C>G p.P69= | Silent (SNP) | VAF 23/64 reads (36%) | called by muse, mutect2, varscan2
- RBM33 | c.453C>T p.H151= | Silent (SNP) | VAF 16/217 reads (7%) | catalogued as rs79072920, COSV55296543; called by muse, mutect2
- RIPK4 | c.1725C>T p.N575= (on ENST00000352483; = p.N527= on NM_020639.3) | Silent (SNP) | VAF 25/73 reads (34%) | catalogued as rs143300354; called by muse, mutect2, varscan2
- TUBB4A | c.1227C>T p.T409= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as rs1482421503, COSV51152859; called by muse, mutect2, varscan2
- VIRMA | c.2193G>A p.L731= | Silent (SNP) | VAF 53/143 reads (37%) | called by muse, mutect2, varscan2
- COBLL1 | c.344+138del | Intron (DEL) | VAF 6/26 reads (23%) | catalogued as rs201476254; called by mutect2, varscan2
- CSN1S1 | c.*150C>G | 3'UTR (SNP) | VAF 6/10 reads (60%) | called by muse, mutect2, varscan2
- GALNT9 | c.419+9924C>G | Intron (SNP) | VAF 58/122 reads (48%) | called by muse, mutect2, varscan2
- HADHB | c.110-2471C>T | Intron (SNP) | VAF 7/16 reads (44%) | catalogued as COSV58547302; called by muse, mutect2
- HNRNPH1 | c.*52C>T | 3'UTR (SNP) | VAF 14/79 reads (18%) | called by muse, mutect2, varscan2
- KALRN | c.4929+22159C>T | Intron (SNP) | VAF 5/12 reads (42%) | called by muse, mutect2, varscan2
- MS4A4A | c.41+2012G>C | Intron (SNP) | VAF 3/31 reads (10%) | catalogued as rs1400925732; called by muse, mutect2
- PTPRE | c.1008-66C>T | Intron (SNP) | VAF 5/11 reads (45%) | catalogued as rs950893029; called by muse, mutect2, varscan2
- SYTL2 | c.1459+2387C>G | Intron (SNP) | VAF 6/60 reads (10%) | called by muse, mutect2
- TAFA4 | c.*1C>T | 3'UTR (SNP) | VAF 42/86 reads (49%) | catalogued as rs767390441, COSV55144757; called by muse, mutect2, varscan2
- VEGFD | c.-43G>A | 5'UTR (SNP) | VAF 24/53 reads (45%) | called by muse, mutect2, varscan2
- XIST | n.9398C>A | RNA (SNP) | VAF 44/126 reads (35%) | called by muse, mutect2, varscan2
